Somatic mutation profile of cancer-model specimen HCM-CSHL-0514-C50-85B (3D Organoid, passage 6; aliquot HCM-CSHL-0514-C50-85B-01D-A88G-36), derived from the primary tumor of HCMI case HCM-CSHL-0514-C50, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G1.
Specimen HCM-CSHL-0514-C50-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f97bde3-f59a-4f8f-adfa-63ee9bc9ca14.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0514-C50-10A (Blood Derived Normal), aliquot HCM-CSHL-0514-C50-10A-01D-A88G-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ea9bdf1-c709-4fda-b85d-914870f1ee7d

The open-access MAF lists 92 somatic variants for this specimen: 67 protein-altering or splice-affecting, 22 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 22, Nonsense Mutation 7, Intron 3, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2329G>T p.V777L | Missense Mutation (SNP) | VAF 52/420 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as rs121913471, COSV54062385, COSV54062767, COSV54069186; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 28/337 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- TP53 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 63/503 reads (13%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen possibly damaging (0.45); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACADSB | c.98C>G p.S33* | Nonsense Mutation (SNP) | VAF 45/313 reads (14%) | catalogued as COSV62550729; called by muse, mutect2, varscan2
- APC | c.5021G>C p.G1674A | Missense Mutation (SNP) | VAF 50/426 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1561597087; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARID4B | c.1988G>A p.R663Q | Missense Mutation (SNP) | VAF 40/499 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs746493341; called by muse, mutect2
- BNC2 | c.2815G>A p.A939T | Missense Mutation (SNP) | VAF 83/487 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs140165119, COSV66160260, COSV66162434; called by muse, mutect2, varscan2
- CDH1 | c.1342C>T p.Q448* | Nonsense Mutation (SNP) | VAF 22/212 reads (10%) | catalogued as COSV55737768; called by muse, varscan2
- DCTD | c.160A>G p.N54D | Missense Mutation (SNP) | VAF 130/388 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764076068; called by muse, mutect2, varscan2
- DSP | c.8386G>A p.D2796N | Missense Mutation (SNP) | VAF 58/512 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs943247894; called by muse, mutect2, varscan2
- EPHA5 | c.2669C>T p.A890V | Missense Mutation (SNP) | VAF 25/308 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs778795902, COSV56645189; called by muse, mutect2
- FAM171B | c.1780C>T p.H594Y | Missense Mutation (SNP) | VAF 39/439 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.478); catalogued as COSV59001981; called by muse, mutect2
- FSIP2 | c.11414G>A p.R3805H | Missense Mutation (SNP) | VAF 78/297 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs754806977; called by muse, mutect2, varscan2
- IGF2BP1 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 29/297 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs759839830; called by muse, mutect2, varscan2
- ISX | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 36/368 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as COSV58086101, COSV58086365; called by muse, mutect2
- KCNE1 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 73/689 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.336); catalogued as rs199473360, CM097707, COSV100492580; ClinVar: uncertain significance / not provided; called by muse, mutect2
- KCNT1 | c.1606C>T p.R536C (on ENST00000488444; = p.R555C on NM_020822.3) | Missense Mutation (SNP) | VAF 84/467 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs774249834; called by muse, mutect2, varscan2
- KMT2A | c.8947C>T p.P2983S | Missense Mutation (SNP) | VAF 37/344 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV63284930; called by muse, mutect2, varscan2
- LRFN1 | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 44/532 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50504613; called by muse, mutect2
- MTOR | c.5245C>G p.R1749G | Missense Mutation (SNP) | VAF 88/258 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63878425; called by muse, mutect2, varscan2
- NCR1 | c.229C>T p.R77W | Missense Mutation (SNP) | VAF 98/908 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs142746677, COSV52555296; called by muse, mutect2
- NUP155 | c.3346G>C p.E1116Q (on ENST00000231498 / NM_153485.3; = p.E1057Q on NM_004298.4) | Missense Mutation (SNP) | VAF 13/286 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51533591; called by muse, mutect2
- PCLO | c.5065dup p.T1689Nfs*6 | Frame Shift Ins (INS) | VAF 68/378 reads (18%) | catalogued as COSV61636220; called by mutect2, varscan2
- PHLDA1 | c.164C>T p.S55L | Missense Mutation (SNP) | VAF 68/596 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as rs1335178342; called by muse, mutect2, varscan2
- SOBP | c.1982G>A p.R661Q | Missense Mutation (SNP) | VAF 61/656 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.171); catalogued as rs867117792; called by muse, mutect2
- TF | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 75/211 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as rs371174384; called by muse, mutect2, varscan2
- TMEM35A | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 70/528 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.956); catalogued as COSV54502852, COSV54503909; called by muse, mutect2, varscan2
- ZIM3 | c.838C>T p.Q280* | Nonsense Mutation (SNP) | VAF 36/502 reads (7%) | catalogued as COSV54143099; called by muse, mutect2
- ZKSCAN7 | c.1094C>T p.P365L | Missense Mutation (SNP) | VAF 61/443 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs543066060; called by muse, mutect2, varscan2
- ZNF672 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 76/900 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.092); catalogued as COSV60637378; called by muse, mutect2
- ABCC9 | c.979G>C p.E327Q | Missense Mutation (SNP) | VAF 31/306 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.088); called by muse, mutect2
- ARHGEF6 | c.2221G>A p.E741K | Missense Mutation (SNP) | VAF 35/523 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); called by muse, mutect2
- CCS | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 40/500 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0.007); called by muse, mutect2
- CT55 | c.393C>A p.S131R | Missense Mutation (SNP) | VAF 30/271 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CYB5B | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 38/398 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DCT | c.788G>T p.G263V | Missense Mutation (SNP) | VAF 43/391 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DDX43 | c.1589T>A p.L530* | Nonsense Mutation (SNP) | VAF 15/263 reads (6%) | called by muse, mutect2
- DLAT | c.500T>C p.V167A | Missense Mutation (SNP) | VAF 33/295 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- DLGAP1 | c.145C>T p.Q49* | Nonsense Mutation (SNP) | VAF 65/636 reads (10%) | called by muse, mutect2, varscan2
- F2 | c.332G>T p.G111V | Missense Mutation (SNP) | VAF 105/327 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- F2RL3 | c.271G>T p.G91W | Missense Mutation (SNP) | VAF 92/942 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GRIPAP1 | c.418C>G p.L140V | Missense Mutation (SNP) | VAF 62/712 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- HIVEP2 | c.2713G>A p.E905K | Missense Mutation (SNP) | VAF 56/419 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- KIF20A | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 44/494 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- KIF7 | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 53/422 reads (13%) | called by muse, mutect2, varscan2
- KMT2C | c.8525dup p.N2842Kfs*2 | Frame Shift Ins (INS) | VAF 59/390 reads (15%) | called by mutect2, varscan2
- MAGEL2 | c.2806C>A p.H936N | Missense Mutation (SNP) | VAF 56/443 reads (13%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MALRD1 | c.5272A>C p.S1758R | Missense Mutation (SNP) | VAF 140/335 reads (42%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- MARF1 | c.256C>T p.L86F | Missense Mutation (SNP) | VAF 67/551 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- MFSD2A | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 51/535 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.115); called by muse, mutect2
- MYO15B | c.6577A>T p.I2193F | Missense Mutation (SNP) | VAF 56/512 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- NUP133 | c.1201G>C p.D401H | Missense Mutation (SNP) | VAF 30/269 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- OGFOD1 | c.156A>C p.E52D | Missense Mutation (SNP) | VAF 96/218 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OR6C74 | c.660C>G p.I220M | Missense Mutation (SNP) | VAF 40/294 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- PCNP | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 50/565 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.059); called by muse, mutect2
- POT1 | c.1100G>C p.R367T | Missense Mutation (SNP) | VAF 45/383 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- PPIP5K2 | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 29/415 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RIOX2 | c.508C>A p.P170T | Missense Mutation (SNP) | VAF 52/539 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TLE4 | c.55C>T p.Q19* | Nonsense Mutation (SNP) | VAF 50/309 reads (16%) | called by muse, mutect2, varscan2
- TNFRSF10B | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 42/411 reads (10%) | SIFT tolerated (0.85); PolyPhen benign (0.005); called by muse, mutect2
- UCHL5 | c.253A>C p.N85H | Missense Mutation (SNP) | VAF 16/221 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); called by muse, mutect2
- UTP20 | c.8007G>A p.M2669I | Missense Mutation (SNP) | VAF 24/350 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2
- WHAMM | c.1885C>G p.H629D | Missense Mutation (SNP) | VAF 43/528 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.288); called by muse, mutect2
- XIRP2 | c.2454T>A p.D818E (on ENST00000628543; = p.D993E on NM_152381.6) | Missense Mutation (SNP) | VAF 39/366 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZBTB7B | c.754G>A p.D252N (on ENST00000292176; = p.D286N on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/656 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.192); called by muse, mutect2
- ZC3H8 | c.463G>A p.G155R | Missense Mutation (SNP) | VAF 52/452 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- ZNF540 | c.709C>T p.H237Y | Missense Mutation (SNP) | VAF 18/384 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2
- ANKRD10 | c.459G>A p.L153= | Silent (SNP) | VAF 18/222 reads (8%) | called by muse, mutect2
- ARFGEF1 | c.4491G>A p.A1497= | Silent (SNP) | VAF 32/322 reads (10%) | catalogued as rs769048042, COSV51609917, COSV51610083; called by muse, mutect2
- ARHGAP23 | c.2217G>A p.A739= | Silent (SNP) | VAF 88/516 reads (17%) | catalogued as rs1454344108; called by muse, mutect2, varscan2
- ATP1B2 | c.534C>A p.V178= | Silent (SNP) | VAF 37/306 reads (12%) | catalogued as COSV100006895; called by muse, mutect2, varscan2
- C14orf93 | c.846G>C p.L282= | Silent (SNP) | VAF 50/457 reads (11%) | called by muse, mutect2, varscan2
- CDKN2B | c.174C>T p.S58= | Silent (SNP) | VAF 42/581 reads (7%) | catalogued as rs531754702; called by muse, mutect2
- DPH7 | c.42G>A p.L14= | Silent (SNP) | VAF 118/675 reads (17%) | called by muse, mutect2, varscan2
- FRMD4A | c.2919C>T p.V973= | Silent (SNP) | VAF 40/414 reads (10%) | called by muse, mutect2, varscan2
- GAD1 | c.1479G>A p.K493= | Silent (SNP) | VAF 31/326 reads (10%) | called by muse, mutect2
- LEMD1 | c.468G>A p.L156= (on ENST00000367151; = p.*109= on NM_001001552.5) | Silent (SNP) | VAF 63/593 reads (11%) | catalogued as COSV100903449; called by muse, mutect2, varscan2
- LSM11 | c.336C>A p.R112= | Silent (SNP) | VAF 59/510 reads (12%) | called by muse, mutect2, varscan2
- LSP1 | c.420G>C p.L140= | Silent (SNP) | VAF 50/452 reads (11%) | called by muse, mutect2, varscan2
- LUZP4 | c.417A>C p.S139= | Silent (SNP) | VAF 40/571 reads (7%) | called by muse, mutect2
- MAST1 | c.2052C>T p.H684= | Silent (SNP) | VAF 44/422 reads (10%) | catalogued as COSV99262844; called by muse, mutect2
- MXRA5 | c.8253G>A p.V2751= | Silent (SNP) | VAF 98/942 reads (10%) | called by muse, mutect2
- OPRL1 | c.552C>T p.P184= | Silent (SNP) | VAF 72/736 reads (10%) | catalogued as rs576005475; called by muse, mutect2
- PAXBP1 | c.2388A>G p.Q796= | Silent (SNP) | VAF 22/346 reads (6%) | catalogued as rs750454132, COSV51611208; called by muse, mutect2
- SETX | c.1467C>T p.V489= | Silent (SNP) | VAF 71/446 reads (16%) | catalogued as rs142093830; ClinVar: likely benign; called by muse, mutect2, varscan2
- STX10 | c.9C>T p.L3= | Silent (SNP) | VAF 18/275 reads (7%) | called by muse, mutect2
- SYT10 | c.537G>C p.P179= | Silent (SNP) | VAF 36/318 reads (11%) | catalogued as COSV57340490, COSV57345326; called by muse, mutect2, varscan2
- TMEM132B | c.2637G>A p.P879= | Silent (SNP) | VAF 34/472 reads (7%) | catalogued as rs191297957; called by muse, mutect2
- UGGT1 | c.222G>A p.E74= | Silent (SNP) | VAF 21/354 reads (6%) | catalogued as COSV52142201, COSV99390931; called by muse, mutect2
- AP002495.1 | c.436+50G>C | Intron (SNP) | VAF 38/319 reads (12%) | called by muse, mutect2, varscan2
- GPS1 | c.33+406C>G | Intron (SNP) | VAF 54/524 reads (10%) | called by muse, mutect2, varscan2
- SMG7 | c.2742+834A>C | Intron (SNP) | VAF 145/487 reads (30%) | called by muse, mutect2, varscan2
